Gene-level copy-number profile of tumor specimen TCGA-EI-6508-01A from TCGA case TCGA-EI-6508, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 48.8 years (17,827 days).
Specimen TCGA-EI-6508-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.e8bb974e-e0e8-42b0-aa8d-27a86939d059.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EI-6508-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/38856d6b-7121-4eca-a8fa-d544093639f5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 18; copy number 2: 7,477; copy number 3: 317; copy number 4: 47,990; copy number 6: 3,518; copy number 7: 39; copy number 8: 1; copy number 9: 455.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EI-6508-01A-11D-1732-01): tumor purity 0.79, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:120,015,179–120,015,257, 1 gene: MIR3144.
- chr6:120,526,294–120,526,400, 1 gene: RNU6-214P.
- chr13:111,865,136–111,901,264, 1 gene: LINC00354.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 455 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,329,411–34,871,582, 455 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
